Gene-level copy-number profile of tumor specimen TCGA-HC-A6AO-01A from TCGA case TCGA-HC-A6AO, project TCGA-PRAD (Prostate Adenocarcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Prostate gland; Age at diagnosis: 52.8 years (19,298 days).
Specimen TCGA-HC-A6AO-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-PRAD.c21423aa-1ce4-43f7-a4fe-76a320c46d5f.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-HC-A6AO-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 803 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b9d5151f-669d-40cc-bcbb-3d844057e548

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 1: 6,386; copy number 2: 51,631; copy number 3: 209; copy number 5: 1,594.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-HC-A6AO-01A-11D-A30D-01): tumor purity 0.77, ploidy 2, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 1,594 genes in 6 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr8:46,028,804–56,776,874, 169 genes, copy number 5 (broad region; genes not listed).
- chr8:61,500,556–71,592,025, 150 genes, copy number 5 (broad region; genes not listed).
- chr8:72,537,225–76,524,356, 69 genes, copy number 5 (within-gene range 3–5) (broad region; genes not listed).
- chr8:76,576,551–76,579,345, 1 gene, copy number 5: AC013509.1.
- chr8:77,399,072–145,066,685, 1,063 genes, copy number 5 (broad region; genes not listed).
- chr15:22,867,052–25,877,211, 142 genes, copy number 5 (within-gene range 1–5) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 4,005. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
